Somatic mutation profile of tumor specimen PCProject_0357_T2_WES (aliquot PCProject_0357_T2_WES_1) from CMI case PCProject_0357, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.5 years (24,641 days).
Specimen PCProject_0357_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6c915b7-a657-4307-9750-8bf4fa682adf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0357_SALIVA (DNA), aliquot PCProject_0357_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09892f86-3f63-4cab-bfc0-d97f338c83ea

The open-access MAF lists 76 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Intron 18, Silent 9, 3'UTR 5, Frame Shift Del 4, Nonsense Mutation 3, 5'Flank 3, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC010522.1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 52/648 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57147647; called by muse, mutect2
- ADRA1A | c.1316T>C p.L439S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1358151435; called by muse, mutect2
- ANAPC7 | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 154/644 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750459818; called by muse, mutect2, varscan2
- BAIAP2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs777916497, COSV58335530; called by muse, mutect2, varscan2
- CFAP65 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs1337387844; called by muse, mutect2
- ELOA2 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55299440; called by muse, mutect2
- ERCC6L2 | c.4145C>T p.S1382F | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs139384710; called by muse, varscan2
- FRMPD4 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as rs147167664, COSV66213829; called by muse, mutect2, varscan2
- IL4I1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 165/762 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.721); catalogued as rs1266787438; called by muse, mutect2, varscan2
- OMA1 | c.775C>G p.R259G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100678201; called by mutect2, varscan2
- OR4C13 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.327); catalogued as rs1475893973; called by muse, mutect2, varscan2
- PSAP | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as rs376015353; called by muse, mutect2, varscan2
- PWWP2A | c.1682A>G p.K561R | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100194140; called by muse, mutect2, varscan2
- TMEM151A | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs780075405, COSV100516890; called by muse, mutect2, varscan2
- TMTC4 | c.427C>T p.H143Y (on ENST00000376234 / NM_001350577.2; = p.H162Y on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1187004586, COSV60893320; called by muse, mutect2, varscan2
- TTN | c.7501C>T p.R2501* (on ENST00000591111; = p.R2455* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs781459488, COSV60161316; ClinVar: uncertain significance; called by mutect2, varscan2
- ACMSD | c.1004_1005del p.F335* | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.5018C>G p.P1673R | Missense Mutation (SNP) | VAF 98/767 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.5017C>T p.P1673S | Missense Mutation (SNP) | VAF 99/766 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CAPN15 | c.3050T>C p.L1017P | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPT2 | c.1644G>T p.M548I | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, varscan2
- CRB1 | c.3073A>T p.S1025C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- CUL4B | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPOR | c.586-3C>G | Splice Region (SNP) | VAF 84/489 reads (17%) | called by muse, mutect2, varscan2
- FCRL5 | c.1605T>G p.H535Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- GIPC1 | c.217A>T p.I73F | Missense Mutation (SNP) | VAF 109/728 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GOLGA8S | c.884T>G p.L295R | Missense Mutation (SNP) | VAF 90/716 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- INPP5D | c.2297G>T p.G766V (on ENST00000445964 / NM_001017915.3; = p.G765V on NM_005541.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- INSM2 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 77/507 reads (15%) | called by muse, mutect2, varscan2
- KMT2D | c.11778del p.Q3927Sfs*52 | Frame Shift Del (DEL) | VAF 48/252 reads (19%) | called by pindel, varscan2
- MRPL35 | c.525_549del p.D175Efs*4 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- PIP4K2A | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- RGS6 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.139); called by muse, mutect2
- SMG7 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2
- SRSF6 | c.634A>C p.S212R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TRIM8 | c.299del p.P100Rfs*95 | Frame Shift Del (DEL) | VAF 43/414 reads (10%) | called by mutect2, pindel, varscan2
- USP39 | c.939C>G p.I313M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ZFPM2 | c.1585A>T p.R529W | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF280B | c.1531C>G p.Q511E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2
- ZSCAN18 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- C6orf132 | c.120C>T p.A40= | Silent (SNP) | VAF 73/315 reads (23%) | called by muse, mutect2, varscan2
- CCDC88B | c.1476G>A p.P492= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs758184933, COSV57267392; called by muse, mutect2, varscan2
- DNAH5 | c.6537G>A p.T2179= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs201482933, COSV54224672; called by muse, mutect2, varscan2
- EVPL | c.4155C>T p.R1385= | Silent (SNP) | VAF 87/583 reads (15%) | catalogued as COSV56907761; called by muse, mutect2, varscan2
- NRXN2 | c.3975C>T p.A1325= | Silent (SNP) | VAF 146/1692 reads (9%) | catalogued as rs779106674, COSV55459980; called by muse, mutect2
- PDZD3 | c.1191C>A p.I397= (on ENST00000531114; = p.I317= on NM_024791.4) | Silent (SNP) | VAF 47/171 reads (27%) | called by muse, mutect2, varscan2
- PIF1 | c.1032T>C p.F344= | Silent (SNP) | VAF 35/263 reads (13%) | called by muse, mutect2, varscan2
- WDR62 | c.4431G>T p.L1477= | Silent (SNP) | VAF 41/416 reads (10%) | catalogued as rs767400310; called by muse, mutect2
- ZFHX4 | c.2859G>A p.Q953= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- ANKRD17 | c.*2G>A | 3'UTR (SNP) | VAF 10/61 reads (16%) | catalogued as rs778581397; called by muse, mutect2, varscan2
- C15orf40 | c.366+132T>C | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs1210782920, COSV58449491; called by muse, varscan2
- C4BPB | c.410-1004T>G | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs770226709; called by mutect2, varscan2
- CSF2RA | c.*145C>T | 3'UTR (SNP) | VAF 24/329 reads (7%) | catalogued as rs750257726, COSV100817396; called by muse, mutect2
- DEAF1 | c.1593+2638A>G | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as rs1370714837, COSV104423365; called by muse, mutect2, varscan2
- FBLN5 | c.990-336C>T | Intron (SNP) | VAF 14/132 reads (11%) | catalogued as rs1302973428; called by muse, mutect2
- FCHO2 | c.914+716del | Intron (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- GP6 | c.*617T>C | 3'UTR (SNP) | VAF 32/778 reads (4%) | called by muse, mutect2
- HACD1 | c.257+1361T>A | Intron (SNP) | VAF 9/91 reads (10%) | catalogued as rs1554817930; called by muse, mutect2, varscan2
- IGHD1-1 | chr14:105922264 C>T | 5'Flank (SNP) | VAF 16/238 reads (7%) | catalogued as rs781926418; called by muse, mutect2
- ITGA7 | c.2136-23A>G | Intron (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- MYOCD | c.2245+15_2245+16del | Intron (DEL) | VAF 13/69 reads (19%) | called by pindel, varscan2
- OAS2 | c.-20C>T | 5'UTR (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- PADI4 | c.340+485A>G | Intron (SNP) | VAF 18/114 reads (16%) | catalogued as rs1036598090; called by muse, varscan2
- PATJ | c.*1975C>G | 3'UTR (SNP) | VAF 8/34 reads (24%) | catalogued as rs1178016157; called by mutect2, varscan2
- PTPN18 | c.414+2592A>G | Intron (SNP) | VAF 12/48 reads (25%) | catalogued as rs1254023457, COSV51558883; called by muse, varscan2
- PTPN18 | c.414+2593A>G | Intron (SNP) | VAF 10/40 reads (25%) | catalogued as rs1419922064, COSV51558941; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790326 T>C | 5'Flank (SNP) | VAF 15/128 reads (12%) | called by muse, varscan2
- RPL26L1 | chr5:172958151 A>C | 5'Flank (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- SULT1C2 | c.278-2250C>G | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as rs1360453092, COSV52266199; called by muse, mutect2
- TMPRSS11F | c.1015+1645C>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100678504; called by muse, mutect2, varscan2
- TNNI2 | c.16-22C>A | Intron (SNP) | VAF 44/472 reads (9%) | called by muse, mutect2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 18/120 reads (15%) | called by muse, varscan2
- WNK4 | c.2295+155A>G | Intron (SNP) | VAF 13/186 reads (7%) | catalogued as rs1432688256; called by muse, mutect2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 32/364 reads (9%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2
- ZNF141 | c.226+13803A>G | Intron (SNP) | VAF 15/136 reads (11%) | called by muse, varscan2
